Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5680, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5680-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (10.5 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(50% CLEAR CELLS,
50% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 4, INVASIVE
INTO RENAL VEIN AND

RENAL SINUS ADIPOSE TISSUE, TUMOR IN LUMEN AT RENAL VEIN
MARGIN. (SEE COMMENT).

(B) LEFT ADRENAL GLAND:

METASTATIC CONVENTIONAL RENAL CELL CARCINOMA IN ADRENAL GLAND.

COMMENT

The renal cell carcinoma is mainly composed of cells with Fuhrman nuclear grade 3 features, with few foci of Fuhrman grade 4 tumor. Tumor extensively invades into the renal sinus adipose tissue. The renal vein is filled with tumor, and tumor protrudes from the lumen at the renal vein margin. However, there is no tumor in the wall of the renal vein at the margin. The perinephric adipose tissue appears to be free of tumor. No lymph nodes were grossly identified.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - An 18.0 x 13.0 x 7.0 cm radical nephrectomy specimen with attached grossly unremarkable portion of ureter (3.0 cm in length and 0.4 cm in diameter).

A 10.5 x 10.0 x 6.0 cm renal mass is identified at the upper pole of the kidney. The cut surface of the mass is yellow-tan with areas of necrosis, hemorrhage, and focal solid firm areas. Grossly, the tumor involves the renal vein and protrudes 1.2 cm beyond the renal vein resection margin. The tumor also involves the renal sinus adipose tissue, but does not involve the renal calyces. The tumor is grossly 0.1 cm from the resection margin of Gerota's fascia.

The remainder of the renal parenchyma is unremarkable. No lymph nodes were identified in the renal hilum or adjacent adipose tissue.

INK CODE: Green - resection margin of Gerota's fascia.

SECTION CODE: A1, renal artery resection margin, en face; A2, renal vein margin with tumor, en face; A3, renal vein tumor thrombus; A4-A6, tumor with resection margin of Gerota's fascia; A7-A15, representative sections from the tumor; A16-A18, tumor with adipose tissue of renal sinus and calyx; A19, A20, uninvolved renal parenchyma.

(B) LEFT ADRENAL GLAND - A 3.7 x 2.5 x 1.5 cm adrenal gland with attached fibroadipose tissue.

A 3.2 x 2.5 x 1.5 cm mass is identified within the medulla. The cut surface of the mass is red-brown and soft with no hemorrhage or necrosis. The adrenal cortex is atrophic. A portion of the adrenal mass is submitted for possible electron microscopic study. The remainder of the tumor is submitted in B1-B6. The uninvolved adrenal parenchyma is submitted in B7.

[page 2 of 2]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 0fdc9b45-4e99-4499-84bc-ac75c11c12fc (TCGA-CJ-5680.D93A58BD-230C-4B68-A4B5-9B5678C2DD88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).